Surgical pathology report (de-identified scan), TCGA case TCGA-XE-A8H5, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-A8H5-01A (Primary Tumor).

[page 1 of 2]
Ord #=
SURGICAL PATHOL
Modifiers:

RESULTED

Collect

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Right testicle

Clinical History
Right testicular mass

ICD-O-3
Seminoma NOS 9061/3
C62.9
Site (R) Testis NOS C62.9
(R) Testis NOS C62.9
JW 11/24/13

Gross Description

Right testicle: Received in formalin and consists of a 166-gm testicle and spermatic cord measuring 9 x 6.5 x 5 cm. The spermatic cord measures 6 cm in length and 2.2 cm in diameter. The surface is inked black. Serially sectioning reveals pale tan fleshy appearance with areas of necrosis measuring 5.5 x 4.5 x 3.5 cm. The tunica vaginalis is freely mobile and non-adherent. Cassette summary:

- 1 spermatic cord, surgical margin
- 2 spermatic cord, middle section
- 3 spermatic cord, peritesticular
- 4 tumor and tunica vaginalis
- 5 tumor and tunica vaginalis
- 6 tumor and pink area
- 7 tumor and necrotic area
- 8 tumor and necrotic area

Date of Dictation:

Gross Description By:
Attending Pathologist:

Microscopic Description
Performed.

Final Pathologic Diagnosis
Specimen Type: Radical Orchiectomy

[page 2 of 2]
Laterality: Right
Focality: Unifocal
Tumor Size: 5.5 x 4.5 x 3.5 cm.
Histologic Type: Seminoma
Intratubular germ cell neoplasia is not identified.
Tumor is limited to the testis. Tumor does not involve rete testis, epididymis, peri-hilar fat, spermatic cord, tunica vaginalis or scrotal wall.
Margin: Spermatic cord margin is negative for tumor.

Pathologic Tumor Stage: pT1aNXMX(Stage I)

Attending Pathologist(s):

Electronically Signed Out

Procedures/Addenda

Addendum Surgical Pathology

Status of Procedure/Addendum: Signed Out

Date of Procedure/Addendum Ordered:

Date of Procedure/Addendum Signed Out:

ADDENDUM

Lymphovascular invasion: Not identified.

Attending Pathologist:

***Electronically Released By

IHC/AA Discrepancy		✓
Case is Circled		

Source: NCI Genomic Data Commons file a4e85f69-621f-41ac-96e3-e51ba79fe714 (TCGA-XE-A8H5.82DE452E-B831-4D7D-ADF3-4853D930DBBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).